Somatic mutation profile of tumor specimen HCM-CSHL-0063-C18-01A (aliquot HCM-CSHL-0063-C18-01A-01D-A768-36) from HCMI case HCM-CSHL-0063-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 75.1 years (27,438 days).
Specimen HCM-CSHL-0063-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3944bb1f-4f56-42f0-a82b-44d09b0c6505.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0063-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0063-C18-10A-01D-A768-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c92a31d2-d091-43f8-91c2-fca6dc56bf4c

The open-access MAF lists 140 somatic variants for this specimen: 101 protein-altering or splice-affecting, 23 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 23, Intron 7, Nonsense Mutation 6, Frame Shift Del 4, Frame Shift Ins 4, 5'UTR 2, 3'Flank 2, RNA 2, 3'UTR 2, Splice Site 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 74/458 reads (16%) | catalogued as rs137854568, CM910029, COSV57324169; ClinVar: pathogenic; called by muse, varscan2
- EVC | c.1018C>T p.R340* | Nonsense Mutation (SNP) | VAF 56/442 reads (13%) | catalogued as rs121908425, CM000508; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 144/403 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTN4 | c.2507C>T p.S836L | Missense Mutation (SNP) | VAF 72/451 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs766882748, COSV53151095; called by muse, mutect2, varscan2
- ADGRA1 | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1395747433; called by muse, mutect2
- ADRA2A | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs748646629, COSV54526796, COSV54529199; called by muse, mutect2, varscan2
- APC | c.4325del p.P1442Lfs*31 | Frame Shift Del (DEL) | VAF 23/164 reads (14%) | catalogued as COSV57328830; called by mutect2, pindel, varscan2
- ATP8A2 | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 24/173 reads (14%) | catalogued as rs759057352, COSV54947743; called by muse, mutect2, varscan2
- BOP1 | c.1600G>A p.G534R | Missense Mutation (SNP) | VAF 116/414 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs1184030561, COSV58189895; called by muse, mutect2, varscan2
- C2CD4C | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.031); catalogued as rs941101868; called by muse, mutect2, varscan2
- CARD11 | c.1720G>A p.V574I | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs773909937, COSV62754978, COSV62755085; called by muse, mutect2, varscan2
- CCAR1 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs748256307, COSV56268129, COSV56268161; called by muse, varscan2
- CEACAM3 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.046); catalogued as rs782766786; called by muse, mutect2, varscan2
- COL11A1 | c.1696G>T p.V566F | Missense Mutation (SNP) | VAF 42/255 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as COSV62185294; called by muse, varscan2
- COL22A1 | c.3935G>T p.G1312V | Missense Mutation (SNP) | VAF 52/304 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57345176; called by muse, mutect2, varscan2
- COL5A2 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 63/355 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs766179958; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTU1 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.737); catalogued as rs1026519079; called by muse, mutect2
- CYB5D1 | c.263C>T p.T88I | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54683606; called by muse, mutect2, varscan2
- DDX3Y | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.789); catalogued as rs867970646; called by muse, mutect2, varscan2
- EIF4A2 | c.939T>G p.D313E | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs748724172; called by muse, mutect2, varscan2
- FAM155B | c.554dup p.N185Kfs*36 | Frame Shift Ins (INS) | VAF 42/136 reads (31%) | catalogued as rs749254240; called by mutect2, varscan2
- FAT4 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 40/253 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1165902550, COSV67882453; called by muse, mutect2, varscan2
- FBXL7 | c.1081G>A p.G361S | Missense Mutation (SNP) | VAF 42/285 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs375930592; called by muse, mutect2, varscan2
- FER1L6 | c.3947G>A p.R1316Q | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs770709548, COSV67551235; called by muse, mutect2, varscan2
- FGF3 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs782801923; called by muse, mutect2, varscan2
- FMO1 | c.1421G>A p.R474H | Missense Mutation (SNP) | VAF 38/214 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs28360433; called by muse, mutect2, varscan2
- FNDC1 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 38/218 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs778194307; called by muse, mutect2, varscan2
- GABBR2 | c.1822G>A p.D608N | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs978945843, COSV52309784; called by muse, mutect2, varscan2
- GNAS | c.1021G>A p.G341R | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.005); catalogued as rs777234998, COSV58348517; called by muse, mutect2, varscan2
- GPHB5 | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 41/280 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs191071731; called by muse, mutect2, varscan2
- HMCN1 | c.9887G>A p.R3296Q | Missense Mutation (SNP) | VAF 35/307 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs771635945, COSV99628838; called by muse, mutect2, varscan2
- IGHE | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 43/211 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as rs782245796; called by muse, mutect2, varscan2
- KIAA0825 | c.3012dup p.F1005Ifs*3 | Frame Shift Ins (INS) | VAF 15/98 reads (15%) | catalogued as rs776803745; called by mutect2, varscan2
- KPTN | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs1193041866; called by muse, mutect2, varscan2
- LTF | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 36/258 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs750868282; called by muse, mutect2, varscan2
- MARCO | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs376695698; called by muse, mutect2, varscan2
- MICAL3 | c.3958C>T p.R1320W | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.849); catalogued as rs768258471, COSV71588742; called by muse, mutect2, varscan2
- MRGPRX1 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.386); catalogued as rs567589026, COSV57107622; called by muse, mutect2
- MYO9B | c.5378G>A p.R1793Q | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as rs764277555; called by muse, mutect2, varscan2
- NINL | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs762025575; called by muse, mutect2, varscan2
- OR2T12 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 40/422 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as rs764836025, COSV58776972; called by muse, varscan2
- OTOG | c.4147G>A p.E1383K | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.068); catalogued as COSV61131390; called by muse, mutect2
- OTUB1 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 74/426 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1254707597, COSV55357778, COSV99735819; called by muse, mutect2, varscan2
- PCDHA1 | c.2060C>T p.A687V | Missense Mutation (SNP) | VAF 106/592 reads (18%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs782810018; called by muse, mutect2, varscan2
- PCDHA10 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 168/1024 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.072); catalogued as COSV100251756; called by muse, mutect2, varscan2
- PCDHA12 | c.745G>A p.V249I | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.736); catalogued as rs976376933; called by muse, mutect2
- PCSK1 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 99/687 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1460160220; called by muse, mutect2, varscan2
- PKD1L1 | c.1784G>A p.R595Q | Missense Mutation (SNP) | VAF 46/271 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs200343133, COSV56963991, COSV99221622; called by muse, mutect2, varscan2
- PXMP4 | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 47/284 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs773129070; called by muse, mutect2, varscan2
- RILPL1 | c.421G>T p.D141Y | Missense Mutation (SNP) | VAF 49/261 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV65300938; called by muse, mutect2, varscan2
- RTL1 | c.395G>T p.R132L | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV101128316; called by muse, mutect2, varscan2
- SALL1 | c.1493G>A p.R498H | Missense Mutation (SNP) | VAF 92/290 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs997918353; called by muse, mutect2, varscan2
- SEMA3D | c.2194G>A p.E732K | Missense Mutation (SNP) | VAF 78/473 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs749668447, COSV52393626; called by muse, mutect2, varscan2
- SEMA4B | c.1555G>C p.V519L | Missense Mutation (SNP) | VAF 55/322 reads (17%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.918); catalogued as rs751639413; called by muse, mutect2, varscan2
- SEPTIN4 | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs371900167; called by muse, mutect2, varscan2
- SIAH3 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 115/648 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs762491862, COSV68551972; called by muse, mutect2, varscan2
- SIGLECL1 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1222802505, COSV57061964; called by muse, mutect2
- SP140 | c.202C>T p.R68* | Nonsense Mutation (SNP) | VAF 11/136 reads (8%) | catalogued as rs143791311; called by muse, mutect2
- SSH2 | c.2756dup p.E920Rfs*22 | Frame Shift Ins (INS) | VAF 20/80 reads (25%) | catalogued as rs752567808; called by mutect2, varscan2
- THBD | c.1663G>A p.A555T | Missense Mutation (SNP) | VAF 51/283 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.075); catalogued as COSV65702374; called by muse, mutect2, varscan2
- TIAM1 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.998); catalogued as rs771808182, COSV99735379; called by muse, mutect2, varscan2
- TP53 | c.723del p.C242Afs*5 | Frame Shift Del (DEL) | VAF 64/362 reads (18%) | catalogued as COSV53025058, COSV53153033, COSV53211006; called by mutect2, pindel, varscan2
- TRPS1 | c.1748A>G p.Y583C (on ENST00000220888 / NM_001330599.2; = p.Y596C on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/483 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as CD134240; called by muse, mutect2, varscan2
- TTN | c.2735G>A p.R912H (on ENST00000591111; = p.R866H on NM_003319.4) | Missense Mutation (SNP) | VAF 77/431 reads (18%) | PolyPhen benign (0.003); catalogued as rs766770644; called by muse, mutect2, varscan2
- A3GALT2 | c.864G>T p.W288C | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAM19 | c.540G>C p.K180N | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AHNAK2 | c.6313G>T p.V2105L | Missense Mutation (SNP) | VAF 116/950 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.233); called by muse, varscan2
- APC | c.1940C>T p.A647V | Missense Mutation (SNP) | VAF 58/402 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ARRDC2 | c.372C>A p.H124Q | Missense Mutation (SNP) | VAF 48/233 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC18 | c.248del p.N83Tfs*38 | Frame Shift Del (DEL) | VAF 17/67 reads (25%) | called by mutect2, pindel, varscan2
- COL4A5 | c.310C>A p.P104T | Missense Mutation (SNP) | VAF 85/266 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSPG4 | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- CYP1B1 | c.1430A>C p.K477T | Missense Mutation (SNP) | VAF 103/626 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DHX30 | c.1801C>T p.R601* (on ENST00000445061 / NM_138615.3; = p.R562* on NM_014966.3) | Nonsense Mutation (SNP) | VAF 55/273 reads (20%) | called by muse, mutect2, varscan2
- DPY19L2 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- DTL | c.2191T>C p.*731Qext*4 | Nonstop Mutation (SNP) | VAF 28/146 reads (19%) | called by muse, mutect2, varscan2
- EIF4G2 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- GPR149 | c.516G>T p.W172C | Missense Mutation (SNP) | VAF 69/422 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPX6 | c.186G>T p.K62N | Missense Mutation (SNP) | VAF 15/170 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); called by muse, mutect2
- ICE1 | c.5312G>A p.G1771E | Missense Mutation (SNP) | VAF 69/368 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITCH | c.749C>T p.P250L (on ENST00000262650 / NM_001257137.3; = p.P209L on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/503 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- KIF21B | c.1001C>T p.S334L | Missense Mutation (SNP) | VAF 34/215 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MAP10 | c.479G>T p.W160L | Missense Mutation (SNP) | VAF 29/461 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2
- MGAT5 | c.273dup p.N92* | Frame Shift Ins (INS) | VAF 28/147 reads (19%) | called by mutect2, pindel, varscan2
- NBEA | c.5641A>T p.N1881Y | Missense Mutation (SNP) | VAF 25/236 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.254); called by muse, mutect2
- NLGN4X | c.2051C>T p.S684L | Missense Mutation (SNP) | VAF 66/243 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- NME8 | c.1741C>A p.L581I | Missense Mutation (SNP) | VAF 38/291 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- NPIPB11 | c.431C>G p.T144S | Missense Mutation (SNP) | VAF 38/718 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.621); called by muse, mutect2
- PNLIPRP3 | c.668G>T p.R223L | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- RASGRP1 | c.1316G>A p.R439K | Missense Mutation (SNP) | VAF 45/258 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ROBO1 | c.84T>G p.I28M | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- SACS | c.5945G>T p.G1982V | Missense Mutation (SNP) | VAF 46/256 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- SLC30A1 | c.1263del p.F421Lfs*4 | Frame Shift Del (DEL) | VAF 33/223 reads (15%) | called by mutect2, pindel, varscan2
- SWT1 | c.166-17_166-8delinsAAATGATAGACTTTTTTTTTTAA p.X56_splice | Splice Site (INS) | VAF 7/28 reads (25%) | called by pindel, varscan2*
- SYNE1 | c.5837C>A p.T1946N (on ENST00000367255 / NM_182961.4; = p.T1953N on NM_033071.3) | Missense Mutation (SNP) | VAF 96/544 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.372); called by muse, varscan2
- TAF15 | c.1492C>T p.R498* (on ENST00000605844 / NM_139215.3; = p.R495* on NM_003487.4) | Nonsense Mutation (SNP) | VAF 109/487 reads (22%) | called by muse, mutect2, varscan2
- TDRD3 | c.1931A>G p.Y644C | Missense Mutation (SNP) | VAF 44/237 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM70 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 61/271 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- VTI1A | c.232A>G p.K78E | Missense Mutation (SNP) | VAF 60/335 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- ZBBX | c.1725G>T p.L575= | Splice Region (SNP) | VAF 8/40 reads (20%) | called by muse, varscan2
- ZNF729 | c.2192A>T p.K731M | Missense Mutation (SNP) | VAF 83/481 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BCO1 | c.1521C>T p.V507= | Silent (SNP) | VAF 78/484 reads (16%) | catalogued as rs760137851, COSV50730287; called by muse, varscan2
- CD22 | c.117C>T p.C39= | Silent (SNP) | VAF 65/305 reads (21%) | catalogued as rs750364404, COSV50071519; called by muse, mutect2, varscan2
- CFP | c.18G>A p.A6= | Silent (SNP) | VAF 39/275 reads (14%) | catalogued as rs1020912849; ClinVar: likely benign; called by muse, mutect2, varscan2
- CR1 | c.3297C>T p.S1099= | Silent (SNP) | VAF 145/881 reads (16%) | catalogued as COSV65465131; called by muse, mutect2, varscan2
- CYP17A1 | c.702C>T p.S234= | Silent (SNP) | VAF 40/260 reads (15%) | catalogued as rs146311005; called by muse, mutect2, varscan2
- DHX34 | c.2445C>T p.P815= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as rs770947952; called by muse, mutect2, varscan2
- DMRTB1 | c.807G>A p.P269= | Silent (SNP) | VAF 37/183 reads (20%) | catalogued as rs533549553, COSV101008378; called by muse, mutect2, varscan2
- EFCAB12 | c.954G>A p.T318= | Silent (SNP) | VAF 39/266 reads (15%) | catalogued as rs374245278, COSV58177268; called by muse, mutect2, varscan2
- FANCD2OS | c.69G>A p.T23= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as rs1369877103; called by muse, mutect2, varscan2
- GJC2 | c.507G>A p.A169= | Silent (SNP) | VAF 18/112 reads (16%) | catalogued as rs1455432608; called by muse, mutect2, varscan2
- HRNR | c.2097C>T p.S699= | Silent (SNP) | VAF 152/765 reads (20%) | catalogued as rs764048595, COSV100912917; called by muse, mutect2, varscan2
- IGDCC4 | c.585C>T p.G195= | Silent (SNP) | VAF 25/175 reads (14%) | catalogued as rs776431286; called by muse, mutect2, varscan2
- KCNC2 | c.240C>T p.G80= | Silent (SNP) | VAF 41/304 reads (13%) | catalogued as rs1174433701, COSV54371889, COSV54376401; called by muse, mutect2, varscan2
- LIPG | c.714C>T p.H238= | Silent (SNP) | VAF 102/405 reads (25%) | catalogued as COSV99724727; called by muse, mutect2, varscan2
- MIER2 | c.1005C>T p.G335= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs773640885; called by muse, mutect2, varscan2
- MKI67 | c.810C>T p.Y270= | Silent (SNP) | VAF 45/269 reads (17%) | catalogued as rs201621002, COSV64072423; called by muse, mutect2, varscan2
- MUC16 | c.24909C>T p.G8303= | Silent (SNP) | VAF 35/252 reads (14%) | called by muse, mutect2, varscan2
- MYT1L | c.2136G>A p.T712= | Silent (SNP) | VAF 82/552 reads (15%) | called by muse, varscan2
- NBL1 | c.519C>T p.H173= | Silent (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
- PCDH1 | c.1824T>C p.N608= | Silent (SNP) | VAF 42/326 reads (13%) | catalogued as rs1428280111; called by muse, mutect2, varscan2
- PCDHA1 | c.141C>T p.R47= | Silent (SNP) | VAF 70/411 reads (17%) | called by muse, mutect2, varscan2
- PDIA5 | c.117G>A p.L39= | Silent (SNP) | VAF 13/110 reads (12%) | called by muse, mutect2, varscan2
- RBFOX1 | c.1119T>C p.D373= | Silent (SNP) | VAF 60/208 reads (29%) | called by muse, mutect2, varscan2
- AC002428.1 | chr5:135922365 G>A | 5'Flank (SNP) | VAF 22/106 reads (21%) | catalogued as rs551085108; called by muse, mutect2, varscan2
- ANKRD24 | c.37-1211C>A | Intron (SNP) | VAF 16/85 reads (19%) | catalogued as rs1423890855; called by muse, mutect2, varscan2
- ARPC3 | c.*210C>T | 3'UTR (SNP) | VAF 33/218 reads (15%) | catalogued as rs1288239534; called by muse, mutect2, varscan2
- ATRNL1 | c.3795+48167C>T | Intron (SNP) | VAF 30/221 reads (14%) | catalogued as rs782186399; called by muse, mutect2, varscan2
- CHRNA4 | c.-41C>T | 5'UTR (SNP) | VAF 39/268 reads (15%) | called by muse, mutect2, varscan2
- DEFB119 | c.61+1368A>C | Intron (SNP) | VAF 57/415 reads (14%) | called by muse, mutect2, varscan2
- EGFLAM | c.2796-18dup | Intron (INS) | VAF 16/122 reads (13%) | called by mutect2, pindel
- MAMLD1 | c.*690C>T | 3'UTR (SNP) | VAF 8/21 reads (38%) | catalogued as rs927968522; called by muse, mutect2, varscan2
- NUMBL | c.249+38A>G | Intron (SNP) | VAF 23/182 reads (13%) | catalogued as rs1023122970; called by muse, varscan2
- OR10D1P | n.631C>A | RNA (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2
- PGAM5P1 | chr5:109884450 C>A | 3'Flank (SNP) | VAF 57/414 reads (14%) | called by muse, mutect2, varscan2
- PRKN | c.1083+3420G>T | Intron (SNP) | VAF 26/195 reads (13%) | catalogued as COSV100627049, COSV58273856; called by muse, mutect2, varscan2
- SREK1 | c.-174T>C | 5'UTR (SNP) | VAF 25/159 reads (16%) | catalogued as rs1255639147, COSV52333286; called by muse, mutect2, varscan2
- SSPOP | n.10406G>A | RNA (SNP) | VAF 37/162 reads (23%) | called by muse, mutect2, varscan2
- TRIM9 | c.1604-3986G>A | Intron (SNP) | VAF 8/56 reads (14%) | catalogued as rs1444297391, COSV53625689; called by muse, mutect2, varscan2
- Z97192.4 | chr22:49657353 G>T | 3'Flank (SNP) | VAF 17/119 reads (14%) | called by muse, mutect2, varscan2
